Gene-level copy-number profile of tumor specimen TCGA-MP-A4TC-01A from TCGA case TCGA-MP-A4TC, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 77.9 years (28,471 days).
Specimen TCGA-MP-A4TC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.3bc084cf-ac47-4ecc-928a-d459c1234f7e.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,484 have no estimate.
https://portal.gdc.cancer.gov/files/220c39c4-7afe-426d-b154-969940f60666

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 38,710; copy number 2: 17,678; copy number 3: 535; copy number 4: 181; copy number 5: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MP-A4TC-01A-11D-A24O-01): tumor purity 0.45, ploidy 1.47, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:19,719,015–19,936,757, 11 genes: OR4N2, OR4H12P, OR4M1, OR4N1P, OR4K6P, OR4K3, OR4K2, OR4K4P, AL391156.1, OR4K5, OR4K1.
- chr19:43,166,256–43,331,430, 7 genes: PSG5, PSG4, CEACAMP10, PSG9, CEACAMP11, CEACAMP4, AC005392.2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 733 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,049,073–56,328,625, 1 gene, copy number 4 (within-gene range 1–4): CRACD.
- chr5:58,198–45,895,970, 708 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr11:75,260,122–75,351,705, 1 gene, copy number 3 (within-gene range 2–3): ARRB1.
- chr11:75,335,092–75,433,203, 5 genes, copy number 3: MIR326, RPS3, SNORD15A, SNORD15B, KLHL35.
- chr11:102,047,437–102,530,750, 17 genes, copy number 5: CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7.
- chr14:63,312,835–63,318,935, 1 gene, copy number 3: GPHB5.

Autosomal genes at a single copy (total copy number 1): 38,710. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
